Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3T0, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3T0-01A (Primary Tumor).

[page 1 of 2]
	JW 33012	

Case Report

DOB:
Physician

Sex:

Received:

Pathologist:

Accession:

Case type: Surgical History

**** Case imported from computer system. The format of this report does not match the original case. ****
**** For cases prior to section "SPECIMEN" may have been added. ****

DIAGNOSIS

(A) LEVEL IIA AND IIIA LYMPH NODES:

Four lymph nodes, no tumor present.

(B) LEVEL IIB, IIIB, IVB AND VB LYMPH NODES:

No tumor present in five of level IIB lymph nodes.

METASTATIC PAPILLARY CARCINOMA OF THYROID IN 3/10 OF LEVEL IIB LYMPH NODES.

METASTATIC PAPILLARY CARCINOMA OF THYROID IN 1/5 LEVEL IVB LYMPH NODES.

No tumor present in six of level V lymph nodes.

(C) INFERIOR RIGHT PRETRACHEAL MASS:

METASTATIC PAPILLARY CARCINOMA OF THYROID IN 2/2 LYMPH NODES.

(D) THYROID, TOTAL THYROIDECTOMY:

PAPILLARY CARCINOMA OF THYROID WITH COMBINED PAPILLARY AND FOLLICULAR COMPONENTS, EXTENDING INTO ADJACENT SOFT TISSUE.

METASTASIS INTO 1/1 PARATHYROID LYMPH NODE.

(E) RIGHT UPPER PARATRACHEAL MASS:

METASTATIC PAPILLARY CARCINOMA OF THYROID IN 3/3 LYMPH NODES.

ICD-O-3

PATH: carcinoma, papillary and follicular, thyroid 8340/3

CQCF: carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

4-312
20

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) LEVEL II AND III A LYMPH NODES - A single piece of fibrofatty tissue (3.5 x 2.0 x 0.8 cm). Four separate lymph nodes are identified within this tissue. They range in maximum dimension from 0.5 to 1.8 cm.

SECTION CODE: A1, largest lymph node bisected; A2, two possible lymph nodes; A3, one possible lymph node.

(B) LEVEL IIB, IIIB, IVB, AND VB LYMPH NODES - A right neck dissection including fibrofatty tissue, muscle folds, lymph nodes, and vascular tissue which is 9.5 x 5.0 x 3.0 cm. The largest lymph node recovered is 3.5 x 3.0 x 2.7 cm, and is grossly positive for tumor. It is located in level 3. Other lymph nodes in level 3 and level 4 are also grossly positive for tumor.

SECTION CODE: Lymph nodes submitted as follows:

Level 2B - B1, three possible lymph nodes; B2, four possible lymph nodes.

Level 3B - representative sections B3, B4, representative sections of largest, grossly positive lymph node; B5, representative sections of additional grossly positive lymph node; B6, B7, four possible lymph nodes, each cassette; B8, three possible lymph nodes.

Lymph nodes from level 4B - B9, one lymph node, bisected; B10, four possible lymph nodes; B11, five possible lymph nodes.

Level 5 lymph nodes: B12, B13, four possible lymph nodes, each cassette.

(C) INFERIOR RIGHT PRETRACHEAL MASS - Two tan ovoid firm nodules measuring

[page 2 of 2]
History Case Pathology Report

DOB:

Sex

Physician:

Received: _____

Pathologist: **

Accession: _____

Case type: Surgical History

1.3 and 0.5 cm, respectively. They are entirely submitted as follows:

SECTION CODE: C1, C2, larger nodule; C3, smaller nodule.

(D) THYROID - A thyroidectomy specimen (7.0 x 4.5 x 2.3 cm). The right lobe contains a tan firm nodule measuring 2.0 cm in greatest dimension. A second nodule is present in the left lobe (0.8 cm).

INK CODE: Black - capsule.

SECTION CODE: D1-D5, right lobe nodule; D6, right lobe, representative section of uninvolved parenchyma; D7-D8, left lobe nodule; D9, left lobe representative resection.

(E) RIGHT UPPER PARATRACHEAL MASS - Three tan ovoid nodules measuring 3.0, 1.1 and 1.0 cm, respectively in greatest dimension. The cut surfaces are tan and lobulated. All the nodules are submitted in toto as follows:

SECTION CODE: E1-E4, largest nodule; E5, mid size nodule; E6, smallest nodule.

SNOMED CODES

M-80503 M-80506 T-B6000 T-C4100

Source: NCI Genomic Data Commons file 0309c1ce-15a7-4de6-a903-cb1d593238df (TCGA-EL-A3T0.A003614A-E610-4B31-BD3B-6A9B3141E7DB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).